Somatic mutation profile of tumor specimen C3L-05598-03 (aliquot CPT0346280006) from CPTAC case C3L-05598, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 75.1 years (27,423 days).
Specimen C3L-05598-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0c412f0-31ad-4f0f-bc80-37a40541a6ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05598-31 (Blood Derived Normal), aliquot CPT0346360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99025dd3-1e48-4b3d-9003-2f7c4e518c02

The open-access MAF lists 411 somatic variants for this specimen: 248 protein-altering or splice-affecting, 147 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 224, Silent 147, Nonsense Mutation 15, Intron 10, Splice Site 4, Splice Region 2, 3'Flank 2, RNA 2, Frame Shift Del 2, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 138/344 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV52517971, COSV52518546; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 140/401 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- A2M | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as COSV59386274; called by muse, mutect2, varscan2
- ABCA13 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70026142; called by muse, mutect2, varscan2
- ADAM2 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 195/296 reads (66%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as COSV55865564, COSV99697377; called by muse, mutect2, varscan2
- ADAMDEC1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 116/176 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs868610362, COSV56474181; called by muse, varscan2
- ADAMTS12 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 192/503 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs371409097; called by muse, mutect2, varscan2
- ADAMTS16 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 176/436 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56987127; called by muse, mutect2, varscan2
- ADAMTS9 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 150/388 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.076); catalogued as rs773453319, COSV55790673; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1860G>A p.P620= | Splice Region (SNP) | VAF 125/359 reads (35%) | catalogued as rs754436821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY8 | c.1205T>G p.F402C | Missense Mutation (SNP) | VAF 104/410 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV104376900; called by muse, varscan2
- AHNAK | c.17345C>T p.S5782L | Missense Mutation (SNP) | VAF 173/445 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs772135598, COSV57225359; called by muse, mutect2, varscan2
- AKAIN1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.739); catalogued as rs941724144, COSV71420024; called by muse, mutect2, varscan2
- ANK1 | c.5108G>A p.W1703* | Nonsense Mutation (SNP) | VAF 103/155 reads (66%) | catalogued as COSV99225465; called by muse, mutect2, varscan2
- ASXL3 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 171/444 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52456092; called by muse, mutect2, varscan2
- BRINP1 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 106/302 reads (35%) | catalogued as COSV56300506; called by muse, mutect2, varscan2
- BRINP3 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 117/313 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as rs369089898; called by muse, mutect2, varscan2
- C2orf73 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV58310062; called by muse, mutect2, varscan2
- C2orf73 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs1004452312; called by muse, mutect2, varscan2
- CACNA1E | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 143/392 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs763922481; called by muse, varscan2
- CACNA1E | c.5587C>A p.L1863M | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.68); catalogued as COSV99052161; called by muse, mutect2, varscan2
- CASKIN2 | c.2212C>G p.R738G | Missense Mutation (SNP) | VAF 226/591 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV58596408; called by muse, mutect2, varscan2
- CCDC168 | c.17599G>A p.E5867K | Missense Mutation (SNP) | VAF 231/578 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as rs1186358737; called by muse, mutect2, varscan2
- CCDC168 | c.7082C>T p.P2361L | Missense Mutation (SNP) | VAF 214/485 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs1231080867; called by muse, mutect2, varscan2
- CD1E | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 192/550 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63769895; called by muse, mutect2, varscan2
- CD4 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 111/338 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as rs782073553; called by muse, mutect2, varscan2
- CDH17 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 184/367 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs1380771629, COSV50332029, COSV50340574; called by muse, mutect2, varscan2
- CHRM2 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 154/432 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57779598; called by muse, mutect2, varscan2
- CHST11 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 201/484 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.053); catalogued as rs374628300; called by muse, mutect2, varscan2
- CIBAR2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 130/229 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1190062246, COSV101608263; called by muse, mutect2, varscan2
- CLPS | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 147/705 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV52567007; called by muse, mutect2, varscan2
- CSF3R | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 124/327 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs752378580; called by muse, mutect2, varscan2
- CSMD3 | c.5659G>A p.G1887R (on ENST00000297405 / NM_001363185.1; = p.G1783R on NM_052900.3) | Missense Mutation (SNP) | VAF 110/449 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs149542393; called by muse, mutect2, varscan2
- CTNNB1 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 210/525 reads (40%) | catalogued as COSV62697575, COSV62728238; called by muse, mutect2, varscan2
- CYP21A2 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 127/619 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as rs1358140657; called by muse, mutect2, varscan2
- DDX19B | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99850176; called by muse, mutect2, varscan2
- DIPK2B | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 298/358 reads (83%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV101211724; called by muse, mutect2, varscan2
- DNAH11 | c.8317-1G>A p.X2773_splice | Splice Site (SNP) | VAF 119/277 reads (43%) | catalogued as COSV60980717; called by muse, mutect2, varscan2
- DNAH9 | c.4831G>A p.D1611N | Missense Mutation (SNP) | VAF 125/291 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs754488532, COSV52346072; called by muse, mutect2, varscan2
- DUSP22 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 80/367 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs757843915, COSV60524977, COSV60532953; called by muse, mutect2, varscan2
- ENPEP | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV54451293; called by muse, mutect2, varscan2
- ERVMER34-1 | c.899dup p.L300Ffs*13 | Frame Shift Ins (INS) | VAF 143/360 reads (40%) | catalogued as rs779855268; called by mutect2, varscan2
- FAM186A | c.5485C>T p.R1829W | Missense Mutation (SNP) | VAF 228/563 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1041609494; called by muse, mutect2, varscan2
- FAM47C | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 206/278 reads (74%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100792779; called by muse, mutect2, varscan2
- FER1L5 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70069065; called by muse, mutect2, varscan2
- FGF2 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs151141410, COSV52648508; called by muse, mutect2, varscan2
- FMN2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 193/469 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as rs748393494, COSV60431235; called by muse, mutect2, varscan2
- GALNTL6 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV72490571; called by muse, mutect2, varscan2
- HPS4 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 108/285 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV61102511; called by muse, mutect2, varscan2
- HRNR | c.6248G>A p.R2083Q | Missense Mutation (SNP) | VAF 170/406 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770559256, COSV64254986; called by muse, varscan2
- HTR3A | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 161/400 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747021831, COSV55468362; called by muse, mutect2, varscan2
- ICAM2 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99856863; called by muse, mutect2, varscan2
- IFRD2 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 152/403 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371139300; called by muse, mutect2, varscan2
- IGHV3-30 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 136/764 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs746166672; called by muse, mutect2, varscan2
- KCNQ4 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV100714394; called by muse, mutect2, varscan2
- KIF13A | c.3976C>T p.L1326F | Missense Mutation (SNP) | VAF 120/342 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs774472191; called by muse, mutect2, varscan2
- KIF18A | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54184118; called by muse, mutect2, varscan2
- KLHL13 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 216/264 reads (82%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1314523330, COSV53245217; called by muse, mutect2, varscan2
- LRRC74A | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 133/320 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV99372792; called by muse, mutect2, varscan2
- MAGEC1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 208/262 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV53570591; called by muse, mutect2, varscan2
- MORN1 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 207/552 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs766891354; called by muse, mutect2, varscan2
- MRPL15 | c.821T>G p.V274G | Missense Mutation (SNP) | VAF 293/508 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs767805189; called by muse, mutect2, varscan2
- MUC2 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT tolerated (0.39); catalogued as rs1176477762; called by muse, mutect2, varscan2
- NDOR1 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 272/640 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs779205950, COSV100788964; called by muse, mutect2, varscan2
- NES | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 220/473 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs111436671; called by muse, mutect2, varscan2
- NLRP13 | c.2446T>C p.C816R | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1212833423; called by muse, mutect2, varscan2
- NPHS1 | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 164/428 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs866874216, COSV62289826; called by muse, mutect2, varscan2
- NPNT | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 95/313 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as rs143168697; called by muse, mutect2, varscan2
- NPSR1 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs368052535; called by muse, mutect2, varscan2
- NPY1R | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs75841573; called by muse, mutect2, varscan2
- OBP2B | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 93/289 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs782395961, COSV64402192; called by muse, mutect2, varscan2
- OBSCN | c.15869C>T p.P5290L | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52808106; called by muse, mutect2, varscan2
- OR4C5 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 129/334 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs1054464091; called by muse, mutect2, varscan2
- OR4K1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 102/1025 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs149331048, COSV53458632, COSV53459042; called by muse, mutect2, varscan2
- OR4K2 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 125/1548 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.085); catalogued as rs866350693, COSV53848275; called by muse, mutect2
- OR4M1 | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 102/1202 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100271122; called by muse, mutect2
- OR52E8 | c.886A>T p.I296F | Missense Mutation (SNP) | VAF 132/342 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs753420246; called by muse, mutect2, varscan2
- OR5K4 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs746411500, COSV100721422, COSV61584133; called by muse, mutect2, varscan2
- OR5M8 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 162/418 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs867737264, COSV59117762; called by muse, mutect2, varscan2
- OR6F1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 159/402 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57469242; called by muse, mutect2, varscan2
- OR6T1 | c.54del p.S19Vfs*13 | Frame Shift Del (DEL) | VAF 146/368 reads (40%) | catalogued as COSV58310015; called by mutect2, varscan2
- OR6V1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 267/694 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs760856656, COSV69236835; called by muse, mutect2, varscan2
- PAPPA2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 212/516 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs866461390, COSV62773209, COSV62780685; called by muse, mutect2, varscan2
- PARP1 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 148/453 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1044747889; called by muse, mutect2, varscan2
- PCDH15 | c.4519C>T p.P1507S (on ENST00000644397 / NM_001354429.2; = p.I1467= on NM_001142770.3) | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV64739706; called by muse, mutect2, varscan2
- PCDHA13 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 136/384 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1562802468, COSV56481996; called by muse, mutect2, varscan2
- PCDHA9 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 183/520 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV65332150; called by muse, mutect2, varscan2
- PCDHB8 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 126/1157 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50792674; called by muse, mutect2, varscan2
- PDK1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs575410435, COSV56375364; called by muse, mutect2, varscan2
- PGBD4 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 185/488 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764936669, COSV56629119, COSV99855013; called by muse, mutect2, varscan2
- PHF1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 190/508 reads (37%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.587); catalogued as rs762136379; called by muse, mutect2, varscan2
- PHLDB2 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 207/503 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as rs1209433982, COSV67312460; called by muse, mutect2, varscan2
- PLCXD2 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 178/470 reads (38%) | catalogued as rs571921225, COSV67341126; called by muse, mutect2, varscan2
- PLEKHG2 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 221/585 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV52680575; called by muse, mutect2
- PLXDC2 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 227/529 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV65921481; called by muse, mutect2, varscan2
- PPIE | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1251512376; called by muse, mutect2, varscan2
- PPP1R3A | c.2786A>G p.E929G | Missense Mutation (SNP) | VAF 173/421 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1490028752; called by muse, mutect2, varscan2
- PRAMEF2 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 184/490 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.324); catalogued as rs1157068957; called by muse, mutect2, varscan2
- PRAMEF6 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 48/331 reads (15%) | catalogued as rs1451273114; called by muse, mutect2, varscan2
- PRDM14 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 239/429 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868518861, COSV52571649; called by muse, mutect2, varscan2
- PRUNE2 | c.6311G>A p.S2104N | Missense Mutation (SNP) | VAF 310/569 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs867474707; called by muse, mutect2
- PTPRD | c.4021G>A p.E1341K | Missense Mutation (SNP) | VAF 145/397 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1456256399, COSV61986019; called by muse, mutect2, varscan2
- PTPRT | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 169/429 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs372070542; called by muse, mutect2, varscan2
- RAB40AL | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 149/228 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1300469874, COSV99505067; called by muse, mutect2, varscan2
- RAPGEF2 | c.4228C>T p.P1410S | Missense Mutation (SNP) | VAF 112/283 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99075139; called by muse, mutect2, varscan2
- RASAL3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 166/408 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs747036880; called by muse, mutect2, varscan2
- RNF44 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 132/356 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs1187109451; called by muse, mutect2, varscan2
- SCNN1D | c.949C>T p.P317S (on ENST00000338555; = p.P481S on NM_001130413.4) | Missense Mutation (SNP) | VAF 183/487 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776147077; called by muse, mutect2, varscan2
- SDAD1 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 153/436 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs769871264, COSV62403794; called by muse, mutect2, varscan2
- SELE | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 215/530 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779627494; called by muse, mutect2, varscan2
- SEMA6C | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 218/557 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.076); catalogued as rs1336790805; called by muse, mutect2, varscan2
- SHQ1 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 210/504 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57764046; called by muse, mutect2, varscan2
- SIGLEC12 | c.475G>A p.V159M (on ENST00000291707 / NM_053003.4; = p.V41M on NM_033329.2) | Missense Mutation (SNP) | VAF 184/478 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs865831368; called by muse, mutect2, varscan2
- SLC13A5 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 205/477 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs200275193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC28A1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 139/351 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54478931; called by muse, mutect2, varscan2
- SLC6A9 | c.703G>A p.A235T (on ENST00000360584 / NM_201649.4; = p.A181T on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/563 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs200984575, COSV62211951; called by muse, mutect2, varscan2
- SLC9C1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs779690767, COSV59885462; called by muse, mutect2, varscan2
- SLCO1B3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53935134; called by muse, mutect2, varscan2
- SOGA1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 235/587 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs1243577383; called by muse, mutect2, varscan2
- SPAG17 | c.4853G>A p.G1618D | Missense Mutation (SNP) | VAF 146/368 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs755581663; called by muse, mutect2, varscan2
- SPATA16 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 127/397 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs144595913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPHKAP | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 115/370 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60895766; called by muse, mutect2, varscan2
- SYT9 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 161/424 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV100607654; called by muse, mutect2, varscan2
- THSD7B | c.4340G>A p.R1447Q (on ENST00000272643; = p.R1445Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 163/401 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs267598902, COSV55651965; called by muse, mutect2, varscan2
- TMEM268 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.134); catalogued as rs1351858695; called by muse, mutect2, varscan2
- TPTE | c.583C>T p.R195* (on ENST00000618007 / NM_199261.4; = p.R177* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 26/192 reads (14%) | catalogued as rs775040644; called by muse, varscan2
- TRAPPC10 | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 179/440 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs150452816; called by muse, mutect2, varscan2
- TREM1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.129); catalogued as rs1238775931; called by muse, mutect2, varscan2
- TRERF1 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 212/530 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs751381708; called by muse, mutect2, varscan2
- TRIO | c.8309C>T p.S2770L | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs750455503, COSV59989734; called by muse, mutect2, varscan2
- TRMT12 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 402/696 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV100149285; called by muse, mutect2, varscan2
- TRPC6 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 163/458 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs766108737, COSV60257329; called by muse, mutect2, varscan2
- TTN | c.54512G>A p.G18171E (on ENST00000591111; = p.G10747E on NM_003319.4) | Missense Mutation (SNP) | VAF 197/507 reads (39%) | PolyPhen probably damaging (1); catalogued as COSV59903075; called by muse, mutect2, varscan2
- TXNDC2 | c.1594G>A p.E532K (on ENST00000306084 / NM_001098529.2; = p.E465K on NM_032243.6) | Missense Mutation (SNP) | VAF 163/474 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as COSV60154326; called by mutect2, varscan2
- UGT2B10 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 153/442 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55318333; called by muse, mutect2, varscan2
- VPS13D | c.8558C>T p.P2853L | Missense Mutation (SNP) | VAF 98/305 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as rs765261136; called by muse, mutect2, varscan2
- WIPF2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 160/394 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60275443; called by muse, varscan2
- ZNF808 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 154/425 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as COSV63120015; called by muse, mutect2, varscan2
- ABCB11 | c.3821C>G p.A1274G | Missense Mutation (SNP) | VAF 236/587 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC099489.1 | c.6058C>T p.H2020Y | Missense Mutation (SNP) | VAF 183/434 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ACAN | c.2726G>A p.G909D | Missense Mutation (SNP) | VAF 217/473 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADAM30 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 159/468 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AP002512.3 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 201/498 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ARHGAP4 | c.1658A>G p.E553G | Missense Mutation (SNP) | VAF 129/157 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ATCAY | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 127/348 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMP8A | c.949-1G>A p.X317_splice | Splice Site (SNP) | VAF 114/307 reads (37%) | called by muse, mutect2, varscan2
- CAB39L | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 119/296 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACHD1 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 135/353 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CACNA2D1 | c.3027G>A p.M1009I (on ENST00000356253 / NM_001366867.1; = p.M997I on NM_000722.4) | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CAPN14 | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 201/512 reads (39%) | called by muse, mutect2, varscan2
- CCDC182 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 97/312 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC186 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CCDC57 | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 193/501 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- CNOT11 | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 168/393 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- COLGALT2 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 126/324 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- COQ8B | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 163/448 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CPN2 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 192/484 reads (40%) | called by muse, mutect2, varscan2
- CSMD3 | c.5660G>A p.G1887E (on ENST00000297405 / NM_001363185.1; = p.G1783E on NM_052900.3) | Missense Mutation (SNP) | VAF 111/456 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CST6 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 131/380 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND2D | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 39/436 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- DMBT1 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 70/390 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH14 | c.9641C>T p.S3214F (on ENST00000445597; = p.S4222F on NM_001367479.1) | Missense Mutation (SNP) | VAF 138/407 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DVL1 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 165/496 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- EDAR | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 202/471 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF1AX | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 148/189 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ENPEP | c.1002A>T p.E334D | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- FAM181A | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 156/418 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, varscan2
- FGF12 | c.506C>T p.S169L (on ENST00000454309 / NM_021032.5; = p.S107L on NM_004113.6) | Missense Mutation (SNP) | VAF 187/457 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FMN1 | c.2815C>T p.P939S (on ENST00000616417 / NM_001277313.2; = p.P716S on NM_001103184.4) | Missense Mutation (SNP) | VAF 114/299 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMNL1 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 138/388 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- GALNTL6 | c.1672T>G p.C558G | Missense Mutation (SNP) | VAF 170/410 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GARRE1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 148/382 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GET3 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 157/482 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR179 | c.5998C>A p.P2000T (on ENST00000621958; = p.P1999T on NM_001004334.4) | Missense Mutation (SNP) | VAF 278/654 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GRM2 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 196/439 reads (45%) | called by muse, mutect2, varscan2
- GRM7 | c.2468C>T p.T823I | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GTPBP2 | c.705G>A p.E235= | Splice Region (SNP) | VAF 124/291 reads (43%) | called by muse, mutect2, varscan2
- HEATR1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HEBP2 | c.425T>C p.F142S | Missense Mutation (SNP) | VAF 118/173 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEPH | c.461C>T p.S154F (on ENST00000343002; = p.S208F on NM_138737.5) | Missense Mutation (SNP) | VAF 187/253 reads (74%) | SIFT tolerated (0.83); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ICAM4 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 154/384 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IGHV4-34 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 101/294 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- IL31RA | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 129/366 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KLHL30 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- KPNB1 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 107/279 reads (38%) | called by muse, mutect2, varscan2
- KRT2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 147/399 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- LARGE1 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 199/522 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- LRRIQ1 | c.1482A>T p.E494D | Missense Mutation (SNP) | VAF 123/308 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEA12 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 259/311 reads (83%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- MED23 | c.3353C>T p.S1118L | Missense Mutation (SNP) | VAF 162/237 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MS4A7 | c.441A>C p.Q147H | Missense Mutation (SNP) | VAF 178/428 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MUS81 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 106/321 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO15A | c.5368C>T p.P1790S | Missense Mutation (SNP) | VAF 132/338 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MYO18B | c.7204G>A p.E2402K | Missense Mutation (SNP) | VAF 206/520 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- NCF2 | c.997C>G p.P333A | Missense Mutation (SNP) | VAF 153/384 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NSUN6 | c.968A>T p.D323V | Missense Mutation (SNP) | VAF 193/467 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ODAM | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 148/411 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OR14A16 | c.626T>C p.F209S | Missense Mutation (SNP) | VAF 164/400 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- OR1J2 | c.619A>C p.I207L | Missense Mutation (SNP) | VAF 153/440 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR2T27 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 97/757 reads (13%) | called by muse, mutect2, varscan2
- OTOP3 | c.1380G>A p.W460* | Nonsense Mutation (SNP) | VAF 262/629 reads (42%) | called by muse, mutect2, varscan2
- PAK1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 109/253 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- PCDHB3 | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 246/747 reads (33%) | called by muse, mutect2, varscan2
- PCSK1N | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 187/232 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- PI4KB | c.767C>T p.S256F (on ENST00000368873 / NM_001369623.1; = p.S268F on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, varscan2
- PLA2G4F | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 115/297 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PRSS54 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 135/178 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PSG1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 161/456 reads (35%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PSG11 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 140/339 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSG3 | c.371T>G p.I124S | Missense Mutation (SNP) | VAF 178/451 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- PTCHD4 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 174/632 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RALGDS | c.1625C>T p.T542I | Missense Mutation (SNP) | VAF 139/386 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- RC3H2 | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- RHAG | c.658A>C p.M220L | Missense Mutation (SNP) | VAF 130/447 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF17 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ROR1 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 204/533 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RRN3 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSPH10B | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by mutect2, varscan2
- RSPO2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 141/515 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- SCN10A | c.3364C>T p.H1122Y | Missense Mutation (SNP) | VAF 138/348 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SERTM1 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 134/375 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- SI | c.2842G>A p.D948N | Missense Mutation (SNP) | VAF 130/342 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC25A11 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 173/477 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC38A4 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 111/271 reads (41%) | called by muse, mutect2, varscan2
- SP100 | c.1429+1G>A p.X477_splice | Splice Site (SNP) | VAF 93/274 reads (34%) | called by muse, mutect2, varscan2
- SPATA4 | c.553T>A p.S185T | Missense Mutation (SNP) | VAF 49/414 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SRL | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 166/420 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SYNJ1 | c.3412C>T p.P1138S | Missense Mutation (SNP) | VAF 222/557 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- TET3 | c.4763C>T p.S1588F | Missense Mutation (SNP) | VAF 234/586 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- TFEB | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 171/465 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TLR1 | c.1440A>T p.L480F | Missense Mutation (SNP) | VAF 156/423 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR10 | c.2420G>A p.R807K | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMED10 | c.571A>C p.I191L | Missense Mutation (SNP) | VAF 122/293 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TNRC6A | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 163/427 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TRPC4AP | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 146/379 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 88/263 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP6 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 145/427 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- XKR7 | c.1492C>A p.P498T | Missense Mutation (SNP) | VAF 250/597 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.053); called by muse, varscan2
- XPO5 | c.2908_2909del p.M970Gfs*14 | Frame Shift Del (DEL) | VAF 95/279 reads (34%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.2914C>T p.Q972* | Nonsense Mutation (SNP) | VAF 190/660 reads (29%) | called by muse, mutect2, varscan2
- ZNF16 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 429/729 reads (59%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF250 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 156/552 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ZNF274 | c.1645T>G p.S549A (on ENST00000610905; = p.S444A on NM_016324.3) | Missense Mutation (SNP) | VAF 151/440 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF419 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 299/614 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF732 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 179/467 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- ZNF99 | c.706A>T p.K236* | Nonsense Mutation (SNP) | VAF 146/330 reads (44%) | called by muse, mutect2
- ZSCAN18 | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 203/539 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ACACB | c.4788C>T p.F1596= | Silent (SNP) | VAF 155/381 reads (41%) | catalogued as rs755204288, COSV58135186; called by muse, mutect2, varscan2
- ADAMTS13 | c.1257G>A p.G419= | Silent (SNP) | VAF 130/364 reads (36%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.2094C>T p.F698= | Silent (SNP) | VAF 120/350 reads (34%) | catalogued as rs267602783, COSV54503735; called by muse, mutect2, varscan2
- ADAMTSL1 | c.768C>T p.F256= | Silent (SNP) | VAF 168/444 reads (38%) | catalogued as rs1345264130; called by muse, mutect2, varscan2
- ADGRV1 | c.13086G>A p.G4362= | Silent (SNP) | VAF 101/285 reads (35%) | called by muse, mutect2, varscan2
- AGBL3 | c.2157C>T p.F719= | Silent (SNP) | VAF 120/326 reads (37%) | catalogued as rs891105449; called by muse, mutect2, varscan2
- AGTRAP | c.111C>T p.I37= | Silent (SNP) | VAF 164/444 reads (37%) | called by muse, mutect2, varscan2
- ANGPT1 | c.591A>G p.K197= | Silent (SNP) | VAF 203/348 reads (58%) | called by muse, mutect2, varscan2
- ANKRD35 | c.573C>T p.I191= | Silent (SNP) | VAF 110/288 reads (38%) | catalogued as COSV100841873; called by muse, mutect2, varscan2
- ARHGEF1 | c.1356C>T p.F452= | Silent (SNP) | VAF 198/473 reads (42%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.2139C>T p.F713= | Silent (SNP) | VAF 158/390 reads (41%) | called by muse, mutect2, varscan2
- ASIC2 | c.636G>A p.G212= | Silent (SNP) | VAF 196/508 reads (39%) | called by muse, varscan2
- ATP6V0A4 | c.1756C>T p.L586= | Silent (SNP) | VAF 185/525 reads (35%) | catalogued as rs201101333; called by muse, mutect2, varscan2
- ATRN | c.3375C>T p.C1125= | Silent (SNP) | VAF 146/350 reads (42%) | catalogued as rs1184794426; called by muse, mutect2, varscan2
- ATXN1 | c.534C>T p.S178= | Silent (SNP) | VAF 230/566 reads (41%) | catalogued as rs1474983700; called by muse, mutect2, varscan2
- BNIP5 | c.132C>T p.S44= | Silent (SNP) | VAF 242/594 reads (41%) | called by muse, mutect2, varscan2
- BUB3 | c.816C>T p.F272= | Silent (SNP) | VAF 157/372 reads (42%) | catalogued as rs777836898; called by muse, mutect2, varscan2
- C10orf71 | c.1719G>A p.Q573= | Silent (SNP) | VAF 160/423 reads (38%) | called by muse, mutect2, varscan2
- C12orf50 | c.1107C>A p.P369= | Silent (SNP) | VAF 132/352 reads (38%) | called by muse, mutect2, varscan2
- C2orf16 | c.3879A>G p.Q1293= | Silent (SNP) | VAF 103/272 reads (38%) | called by muse, mutect2, varscan2
- C3orf20 | c.1629G>A p.E543= | Silent (SNP) | VAF 157/385 reads (41%) | called by muse, mutect2, varscan2
- CAPSL | c.537G>A p.E179= | Silent (SNP) | VAF 108/261 reads (41%) | called by muse, mutect2, varscan2
- CARD11 | c.1284C>T p.I428= | Silent (SNP) | VAF 206/474 reads (43%) | catalogued as rs757179451; called by muse, mutect2, varscan2
- CCDC185 | c.1206G>A p.V402= | Silent (SNP) | VAF 196/491 reads (40%) | called by muse, mutect2, varscan2
- CD1B | c.753G>A p.G251= | Silent (SNP) | VAF 244/632 reads (39%) | called by muse, mutect2, varscan2
- CD300C | c.336G>A p.V112= | Silent (SNP) | VAF 180/505 reads (36%) | catalogued as rs759568586; called by muse, mutect2, varscan2
- CD300LG | c.195C>T p.I65= | Silent (SNP) | VAF 226/601 reads (38%) | called by muse, mutect2, varscan2
- CDH23 | c.8166C>T p.F2722= | Silent (SNP) | VAF 106/276 reads (38%) | catalogued as rs774041766, COSV56491386; called by muse, mutect2, varscan2
- CEACAM8 | c.471G>A p.V157= | Silent (SNP) | VAF 170/458 reads (37%) | called by muse, mutect2, varscan2
- CLCA4 | c.861C>T p.P287= | Silent (SNP) | VAF 156/412 reads (38%) | catalogued as COSV55371539; called by muse, mutect2, varscan2
- COL6A5 | c.1227C>T p.F409= | Silent (SNP) | VAF 114/316 reads (36%) | catalogued as COSV55202188; called by muse, mutect2, varscan2
- COL6A5 | c.5643C>T p.S1881= (on ENST00000312481; = p.S1877= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 180/488 reads (37%) | called by muse, mutect2, varscan2
- COL8A1 | c.144T>A p.I48= | Silent (SNP) | VAF 191/502 reads (38%) | called by muse, mutect2, varscan2
- CSMD2 | c.3198C>T p.F1066= | Silent (SNP) | VAF 177/495 reads (36%) | catalogued as rs1407986130; called by muse, mutect2, varscan2
- DAGLA | c.1449C>T p.F483= | Silent (SNP) | VAF 240/610 reads (39%) | catalogued as rs1415186989, COSV57197655; called by muse, mutect2, varscan2
- DLEC1 | c.1950C>T p.I650= | Silent (SNP) | VAF 134/355 reads (38%) | catalogued as COSV57304418; called by muse, mutect2, varscan2
- DNAH7 | c.7243C>T p.L2415= | Silent (SNP) | VAF 166/449 reads (37%) | called by muse, mutect2, varscan2
- DOCK4 | c.4554C>T p.S1518= | Silent (SNP) | VAF 107/287 reads (37%) | called by muse, mutect2, varscan2
- EHD1 | c.1503C>T p.F501= | Silent (SNP) | VAF 228/550 reads (41%) | catalogued as rs534200860, COSV57734375; called by muse, mutect2, varscan2
- ENPEP | c.843C>T p.P281= | Silent (SNP) | VAF 138/338 reads (41%) | called by muse, mutect2, varscan2
- EPN3 | c.216G>A p.R72= | Silent (SNP) | VAF 155/458 reads (34%) | catalogued as COSV52141396; called by muse, mutect2, varscan2
- FADS3 | c.1155G>A p.E385= | Silent (SNP) | VAF 197/479 reads (41%) | catalogued as rs748468407; called by muse, mutect2, varscan2
- FARP1 | c.2505C>T p.I835= | Silent (SNP) | VAF 203/509 reads (40%) | catalogued as rs762126916, COSV60338471; called by muse, mutect2, varscan2
- FBXO24 | c.471C>T p.F157= (on ENST00000241071 / NM_033506.3; = p.F195= on NM_012172.5) | Silent (SNP) | VAF 181/430 reads (42%) | catalogued as rs759620146, COSV99575821; called by muse, mutect2, varscan2
- FBXO42 | c.1287C>T p.S429= | Silent (SNP) | VAF 189/460 reads (41%) | catalogued as COSV100981743; called by muse, mutect2, varscan2
- FER1L6 | c.4773G>A p.R1591= | Silent (SNP) | VAF 270/507 reads (53%) | catalogued as rs751596489, COSV67552889; called by muse, mutect2, varscan2
- FLNC | c.6639C>T p.V2213= | Silent (SNP) | VAF 269/598 reads (45%) | catalogued as rs747628268, COSV57961194; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXP1 | c.1116G>A p.K372= | Silent (SNP) | VAF 153/411 reads (37%) | called by muse, mutect2, varscan2
- FOXP1 | c.159C>T p.H53= | Silent (SNP) | VAF 202/485 reads (42%) | catalogued as rs777378675, COSV59515869, COSV59516078; called by muse, mutect2, varscan2
- FREM1 | c.1617G>A p.L539= | Silent (SNP) | VAF 192/534 reads (36%) | called by muse, mutect2, varscan2
- FSIP2 | c.4584G>A p.E1528= | Silent (SNP) | VAF 133/403 reads (33%) | called by muse, mutect2, varscan2
- FYB2 | c.2106G>A p.V702= | Silent (SNP) | VAF 106/286 reads (37%) | called by muse, mutect2, varscan2
- GARRE1 | c.906C>T p.F302= | Silent (SNP) | VAF 150/384 reads (39%) | catalogued as COSV55099796; called by muse, mutect2, varscan2
- GCM2 | c.444G>A p.A148= | Silent (SNP) | VAF 129/354 reads (36%) | catalogued as rs542569618, COSV65275559; called by muse, mutect2, varscan2
- GEM | c.378G>A p.T126= | Silent (SNP) | VAF 130/541 reads (24%) | catalogued as rs763307759, COSV52598628; called by muse, mutect2, varscan2
- GET3 | c.507C>G p.P169= | Silent (SNP) | VAF 159/485 reads (33%) | called by muse, mutect2, varscan2
- GOLGA6L6 | c.1428G>A p.E476= | Silent (SNP) | VAF 163/796 reads (20%) | called by muse, mutect2, varscan2
- GPR27 | c.885C>T p.L295= | Silent (SNP) | VAF 163/428 reads (38%) | catalogued as rs149967896; called by muse, mutect2, varscan2
- GRIFIN | c.183C>T p.F61= | Silent (SNP) | VAF 171/420 reads (41%) | called by muse, mutect2, varscan2
- HS6ST3 | c.1116C>T p.F372= | Silent (SNP) | VAF 199/434 reads (46%) | catalogued as rs747357678, COSV65015726; called by muse, mutect2, varscan2
- HYDIN | c.13800G>A p.K4600= | Silent (SNP) | VAF 166/369 reads (45%) | called by muse, mutect2, varscan2
- ICAM2 | c.66G>A p.S22= | Silent (SNP) | VAF 82/246 reads (33%) | catalogued as rs147443492, COSV99857008; called by muse, mutect2, varscan2
- IGHG3 | c.666G>A p.R222= | Silent (SNP) | VAF 207/547 reads (38%) | called by muse, mutect2, varscan2
- IGHV3-21 | c.117C>T p.L39= | Silent (SNP) | VAF 191/879 reads (22%) | catalogued as rs377637193; called by muse, mutect2, varscan2
- IGLV3-9 | c.198C>T p.I66= | Silent (SNP) | VAF 156/409 reads (38%) | catalogued as rs374490303; called by muse, mutect2, varscan2
- JPH3 | c.1116G>A p.R372= | Silent (SNP) | VAF 202/303 reads (67%) | catalogued as rs375238392; called by muse, mutect2, varscan2
- KIF1A | c.1152C>T p.Y384= | Silent (SNP) | VAF 103/338 reads (30%) | catalogued as rs776874494, COSV100240157, COSV57506685; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHL30 | c.1161G>A p.L387= | Silent (SNP) | VAF 96/316 reads (30%) | catalogued as rs370836245; called by muse, mutect2, varscan2
- KRT1 | c.34C>A p.R12= | Silent (SNP) | VAF 42/398 reads (11%) | catalogued as COSV52868001; called by muse, mutect2, varscan2
- LAMA1 | c.2202C>T p.L734= | Silent (SNP) | VAF 144/386 reads (37%) | called by muse, mutect2, varscan2
- LAMC1 | c.1872C>T p.V624= | Silent (SNP) | VAF 108/285 reads (38%) | catalogued as COSV51177968; called by muse, mutect2, varscan2
- LARGE1 | c.339C>T p.N113= | Silent (SNP) | VAF 199/529 reads (38%) | called by muse, mutect2, varscan2
- LCA5L | c.441G>A p.R147= | Silent (SNP) | VAF 164/396 reads (41%) | catalogued as rs771872757, COSV55748142; called by muse, mutect2, varscan2
- LDLR | c.1131C>T p.C377= | Silent (SNP) | VAF 147/360 reads (41%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1032C>T p.S344= | Silent (SNP) | VAF 239/326 reads (73%) | catalogued as rs750950264; called by muse, mutect2, varscan2
- MUC12 | c.10185G>A p.S3395= (on ENST00000379442; = p.S3252= on NM_001164462.1) | Silent (SNP) | VAF 271/3725 reads (7%) | catalogued as rs780368518; called by muse, mutect2
- MUC12 | c.14616C>T p.A4872= (on ENST00000379442; = p.A4729= on NM_001164462.1) | Silent (SNP) | VAF 179/448 reads (40%) | called by muse, mutect2, varscan2
- MUC16 | c.17460C>T p.I5820= | Silent (SNP) | VAF 140/368 reads (38%) | called by muse, mutect2, varscan2
- MUC5B | c.10935G>A p.R3645= | Silent (SNP) | VAF 184/598 reads (31%) | catalogued as rs745366994; called by muse, mutect2, varscan2
- MYH9 | c.2094C>T p.L698= | Silent (SNP) | VAF 162/360 reads (45%) | catalogued as rs1381074543, COSV53391366; called by muse, mutect2, varscan2
- NAB1 | c.924C>T p.V308= | Silent (SNP) | VAF 115/313 reads (37%) | called by muse, mutect2, varscan2
- NBEAL2 | c.2394C>T p.S798= | Silent (SNP) | VAF 236/554 reads (43%) | catalogued as COSV52763272; called by muse, mutect2, varscan2
- NCAPG2 | c.2970C>T p.F990= | Silent (SNP) | VAF 130/348 reads (37%) | called by muse, mutect2, varscan2
- NDC1 | c.408C>T p.T136= | Silent (SNP) | VAF 162/433 reads (37%) | catalogued as rs894275645; called by muse, mutect2, varscan2
- NPAP1 | c.3459C>T p.F1153= | Silent (SNP) | VAF 92/250 reads (37%) | catalogued as COSV61511051; called by muse, mutect2, varscan2
- NPFFR2 | c.894C>T p.S298= | Silent (SNP) | VAF 207/544 reads (38%) | catalogued as COSV58155716; called by muse, mutect2, varscan2
- OR11H2 | c.480C>T p.F160= (on ENST00000556246; = p.F171= on NM_001197287.1) | Silent (SNP) | VAF 240/2858 reads (8%) | catalogued as rs765130362; called by muse, mutect2
- OR2T33 | c.801C>T p.N267= | Silent (SNP) | VAF 231/684 reads (34%) | called by muse, mutect2, varscan2
- OR4C16 | c.255G>A p.L85= | Silent (SNP) | VAF 149/369 reads (40%) | catalogued as rs1218677295; called by muse, mutect2, varscan2
- OR4K5 | c.57T>C p.S19= | Silent (SNP) | VAF 128/1632 reads (8%) | catalogued as rs765898451; called by muse, mutect2
- OR51T1 | c.357C>T p.A119= | Silent (SNP) | VAF 212/530 reads (40%) | catalogued as COSV59025497; called by muse, mutect2, varscan2
- OR5F1 | c.36C>T p.F12= | Silent (SNP) | VAF 130/378 reads (34%) | catalogued as rs139328258; called by muse, mutect2, varscan2
- OR5K4 | c.9G>A p.R3= | Silent (SNP) | VAF 72/208 reads (35%) | called by muse, mutect2, varscan2
- OR5M10 | c.94C>T p.L32= | Silent (SNP) | VAF 188/457 reads (41%) | called by muse, mutect2, varscan2
- OR5M3 | c.570C>T p.T190= | Silent (SNP) | VAF 173/454 reads (38%) | called by muse, mutect2, varscan2
- OSR2 | c.69C>T p.F23= | Silent (SNP) | VAF 262/923 reads (28%) | catalogued as COSV52555532; called by muse, mutect2, varscan2
- OTUD7A | c.846C>T p.S282= (on ENST00000307050 / NM_001382637.1; = p.S275= on NM_130901.3) | Silent (SNP) | VAF 233/574 reads (41%) | catalogued as COSV61041211; called by muse, mutect2, varscan2
- PARG | c.2751C>T p.F917= | Silent (SNP) | VAF 89/249 reads (36%) | called by muse, mutect2, varscan2
- PARP1 | c.1248G>A p.G416= | Silent (SNP) | VAF 147/455 reads (32%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1548G>A p.K516= | Silent (SNP) | VAF 300/754 reads (40%) | called by muse, mutect2, varscan2
- PCDHB3 | c.2001C>T p.S667= | Silent (SNP) | VAF 244/749 reads (33%) | catalogued as COSV50571540; called by muse, mutect2, varscan2
- PI4KB | c.768C>T p.S256= (on ENST00000368873 / NM_001369623.1; = p.S268= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 126/366 reads (34%) | catalogued as rs1395082756, COSV55016861; called by muse, varscan2
- PIEZO2 | c.2718G>A p.R906= | Silent (SNP) | VAF 132/332 reads (40%) | catalogued as rs1416463198, COSV57430958; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKDCC | c.100A>C p.R34= | Silent (SNP) | VAF 185/420 reads (44%) | called by mutect2, varscan2
- PLAG1 | c.798C>T p.L266= | Silent (SNP) | VAF 150/609 reads (25%) | catalogued as COSV57616439; called by muse, mutect2, varscan2
- PLEKHA7 | c.1413G>A p.Q471= | Silent (SNP) | VAF 186/482 reads (39%) | called by muse, mutect2, varscan2
- PPP6R1 | c.1614C>T p.L538= | Silent (SNP) | VAF 168/396 reads (42%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.1410C>T p.L470= | Silent (SNP) | VAF 146/402 reads (36%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.45G>A p.Q15= | Silent (SNP) | VAF 172/510 reads (34%) | called by muse, mutect2, varscan2
- PRDM14 | c.459C>T p.P153= | Silent (SNP) | VAF 145/552 reads (26%) | catalogued as rs868262210, COSV52575510; called by muse, mutect2, varscan2
- PRKCD | c.2010C>T p.F670= | Silent (SNP) | VAF 93/308 reads (30%) | catalogued as rs781808423, COSV57846669; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKN | c.1062G>A p.G354= | Silent (SNP) | VAF 173/259 reads (67%) | catalogued as rs1395275144; called by muse, mutect2, varscan2
- PSG3 | c.477G>A p.R159= | Silent (SNP) | VAF 118/391 reads (30%) | called by muse, mutect2, varscan2
- PTPRQ | c.2676G>A p.E892= (on ENST00000616559; = p.E850= on NM_001145026.2) | Silent (SNP) | VAF 84/282 reads (30%) | called by muse, mutect2
- RARRES2 | c.450C>T p.F150= | Silent (SNP) | VAF 167/389 reads (43%) | called by muse, mutect2, varscan2
- RNF213 | c.4914C>T p.I1638= | Silent (SNP) | VAF 232/523 reads (44%) | catalogued as rs538274127; called by muse, mutect2, varscan2
- RNF44 | c.597C>T p.P199= | Silent (SNP) | VAF 133/355 reads (37%) | catalogued as rs1463145860; called by muse, mutect2, varscan2
- RSPH10B | c.36G>A p.G12= | Silent (SNP) | VAF 29/77 reads (38%) | called by mutect2, varscan2
- S100A7 | c.42C>T p.I14= | Silent (SNP) | VAF 150/421 reads (36%) | catalogued as COSV64193408; called by muse, mutect2, varscan2
- SCYL1 | c.864C>T p.A288= | Silent (SNP) | VAF 116/315 reads (37%) | catalogued as rs756331964, COSV54214445; called by muse, mutect2, varscan2
- SDK1 | c.2655C>T p.T885= | Silent (SNP) | VAF 130/361 reads (36%) | called by muse, mutect2, varscan2
- SEMA5B | c.1935C>T p.R645= | Silent (SNP) | VAF 157/391 reads (40%) | called by muse, mutect2, varscan2
- SETD4 | c.322C>T p.L108= | Silent (SNP) | VAF 115/271 reads (42%) | catalogued as rs202182458; called by muse, mutect2, varscan2
- SLC11A1 | c.84G>A p.G28= | Silent (SNP) | VAF 226/617 reads (37%) | called by muse, mutect2, varscan2
- SLC24A3 | c.243C>T p.L81= | Silent (SNP) | VAF 134/349 reads (38%) | called by muse, mutect2, varscan2
- SLC25A11 | c.201C>T p.A67= | Silent (SNP) | VAF 172/471 reads (37%) | called by muse, mutect2, varscan2
- SLC28A1 | c.1161G>A p.P387= | Silent (SNP) | VAF 138/352 reads (39%) | catalogued as rs754164862, COSV54481132; called by muse, mutect2, varscan2
- SLC6A7 | c.1023C>T p.I341= | Silent (SNP) | VAF 128/359 reads (36%) | called by muse, mutect2, varscan2
- SMCO2 | c.384C>T p.L128= | Silent (SNP) | VAF 135/341 reads (40%) | called by muse, mutect2, varscan2
- SNX33 | c.1119C>T p.D373= | Silent (SNP) | VAF 202/514 reads (39%) | catalogued as rs1340984686, COSV57912647; called by muse, mutect2, varscan2
- SPOCD1 | c.2022G>A p.R674= | Silent (SNP) | VAF 130/340 reads (38%) | catalogued as COSV57094789; called by muse, mutect2, varscan2
- SREBF2 | c.1983C>T p.T661= | Silent (SNP) | VAF 176/255 reads (69%) | called by muse, mutect2, varscan2
- SRL | c.1341G>A p.G447= | Silent (SNP) | VAF 165/419 reads (39%) | catalogued as rs780383280; called by muse, mutect2, varscan2
- SYCP1 | c.1980C>T p.I660= | Silent (SNP) | VAF 95/257 reads (37%) | called by muse, mutect2, varscan2
- TCEAL6 | c.207G>A p.Q69= | Silent (SNP) | VAF 320/389 reads (82%) | catalogued as COSV65653832; called by muse, mutect2, varscan2
- TM9SF4 | c.1614C>T p.F538= | Silent (SNP) | VAF 149/373 reads (40%) | catalogued as COSV54106254; called by muse, mutect2, varscan2
- TMPRSS4 | c.186C>T p.F62= | Silent (SNP) | VAF 148/405 reads (37%) | called by muse, mutect2, varscan2
- TNN | c.1611G>A p.L537= | Silent (SNP) | VAF 121/299 reads (40%) | catalogued as COSV99513034; called by muse, mutect2, varscan2
- TOR4A | c.948C>T p.S316= | Silent (SNP) | VAF 220/570 reads (39%) | catalogued as rs1226597390; called by muse, mutect2, varscan2
- TRAM1L1 | c.15G>A p.K5= | Silent (SNP) | VAF 103/274 reads (38%) | called by muse, mutect2, varscan2
- TTC7A | c.771C>T p.I257= | Silent (SNP) | VAF 152/413 reads (37%) | catalogued as rs755109997, COSV55408432; called by muse, mutect2, varscan2
- TTN | c.5412C>T p.S1804= (on ENST00000591111; = p.S1758= on NM_003319.4) | Silent (SNP) | VAF 132/342 reads (39%) | catalogued as COSV60383308; called by muse, mutect2, varscan2
- XAF1 | c.246C>T p.R82= | Silent (SNP) | VAF 80/209 reads (38%) | called by muse, mutect2, varscan2
- ZBED9 | c.3672G>A p.Q1224= | Silent (SNP) | VAF 170/484 reads (35%) | catalogued as COSV71729633; called by muse, mutect2, varscan2
- ZNF217 | c.2643C>T p.S881= | Silent (SNP) | VAF 194/501 reads (39%) | called by muse, mutect2, varscan2
- ZNF473 | c.2238C>T p.V746= | Silent (SNP) | VAF 169/479 reads (35%) | catalogued as COSV99568637; called by muse, mutect2, varscan2
- ZNF670 | c.336C>T p.F112= | Silent (SNP) | VAF 160/433 reads (37%) | called by muse, mutect2, varscan2
- AC092070.2 | n.1450C>T | RNA (SNP) | VAF 173/460 reads (38%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*1266C>T | 3'UTR (SNP) | VAF 101/293 reads (34%) | called by muse, mutect2, varscan2
- ATP6AP1L | n.1881C>T | RNA (SNP) | VAF 190/476 reads (40%) | catalogued as COSV66475669; called by muse, mutect2, varscan2
- CWC27 | c.938+3229C>T | Intron (SNP) | VAF 106/315 reads (34%) | called by muse, mutect2, varscan2
- EPN1 | c.-101-816C>T | Intron (SNP) | VAF 162/400 reads (41%) | catalogued as rs757642644; called by muse, mutect2, varscan2
- FBXW10 | c.872-34T>G | Intron (SNP) | VAF 202/601 reads (34%) | called by muse, mutect2, varscan2
- IL1RAP | chr3:190656355 G>A | 3'Flank (SNP) | VAF 201/484 reads (42%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+20006C>T | Intron (SNP) | VAF 138/344 reads (40%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+1980C>T | Intron (SNP) | VAF 126/366 reads (34%) | called by muse, mutect2
- MBNL1 | c.174+40274G>A | Intron (SNP) | VAF 197/450 reads (44%) | catalogued as rs1023952470, COSV56833458; called by muse, mutect2, varscan2
- NSUN4 | c.94-1905C>T | Intron (SNP) | VAF 166/427 reads (39%) | called by muse, mutect2
- OR2T2 | chr1:248441256 G>A | 5'Flank (SNP) | VAF 45/124 reads (36%) | called by mutect2, varscan2
- PGAP2 | c.166-161G>A | Intron (SNP) | VAF 126/311 reads (41%) | called by muse, mutect2, varscan2
- RIMS1 | c.1679-20582G>A | Intron (SNP) | VAF 146/237 reads (62%) | called by muse, mutect2, varscan2
- SEC24A | c.1779+426C>T | Intron (SNP) | VAF 118/325 reads (36%) | called by muse, mutect2, varscan2
- SNORD52 | chr6:31837328 C>T | 3'Flank (SNP) | VAF 169/430 reads (39%) | catalogued as rs776353221; called by muse, mutect2, varscan2
